Surgical pathology report (de-identified scan), TCGA case TCGA-B1-A47N, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-A47N-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: FAT OVERLYING TUMOR, EXCISION -

- A. BENIGN FIBROADIPOSE TISSUE.
- B. NO TUMOR SEEN.

PART 2: CAPSULE OVERLYING TUMOR, EXCISION -

- A. BENIGN FIBROADIPOSE TISSUE WITH CHRONIC INFLAMMATION.
- B. NO TUMOR SEEN.

PART 3: LEFT KIDNEY TUMOR, PARTIAL NEPHRECTOMY -

- A. PAPILLARY RENAL CELL CARCINOMA, TYPE 1, MAXIMAL FUHRMAN NUCLEAR GRADE 3 AND PREDOMINANT NUCLEAR GRADE 2 OUT OF 4 (See comment).
- B. TUMOR IS LIMITED TO THE KIDNEY AND MEASURES 2.2 x 1.9 x 0.8 CM.
- C. TUMOR IS FOCALLY PRESENT AT INKED SURFACE; FOR FINAL MARGIN STATUS, SEE PARTS 1, 2 & 4.
- D. NO VASCULAR INVASION IS IDENTIFIED.
- E. TNM PATHOLOGIC STAGE: pT1a Nx Mx (See synoptic).

PART 4: RENAL TUMOR, DEEP MARGIN, EXCISION -

- A. BENIGN RENAL PARENCHYMA WITH PATCHY CHRONIC INTERSTITIAL INFLAMMATION.
- B. NO TUMOR SEEN.

COMMENT:

Part 3: Immunohistochemistry shows tumor diffusely and strongly positive for CK7 and racemase (P504S). Tumor shows focal positivity for CD10. This immunohistochemical profile is consistent with a papillary renal cell carcinoma.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Partial nephrectomy
LATERALITY: Left
TUMOR SITE: Not specified
FOCALITY: Unifocal
TUMOR SIZE: Greatest dimension: 2.2 cm
Additional dimensions: 1.9 x 0.8 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Papillary renal cell carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G3

PATHOLOGIC STAGING (pTNM):

pT1a
pNX
Number of regional lymph nodes examined: 0

MARGINS:

pMX
Margins uninvolved by invasive carcinoma

ADRENAL GLAND:

Not present

LYMPH-VASCULAR INVASION (LVI): Absent/not identified

1CD-0-3

carcinoma, papillary renal cell 8260/3

Site: Kidney, NOS 664.9

lw
9/27/12

lw
8/20/12

Source: NCI Genomic Data Commons file fffe45f7-dc46-41bf-bfe4-4d14c8208d6e (TCGA-B1-A47N.BBF67449-D59A-46C6-A180-A7546607ED87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).